Somatic mutation profile of tumor specimen HCM-CSHL-1268-C24-06A (aliquot HCM-CSHL-1268-C24-06A-11D-A882-36) from HCMI case HCM-CSHL-1268-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 58.9 years (21,495 days).
Specimen HCM-CSHL-1268-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6947ffd5-ecd6-4e29-af90-661e54f599b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1268-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-1268-C24-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c429b27a-55c4-4568-b9e5-a75f09e0df48

The open-access MAF lists 2,058 somatic variants for this specimen: 1,516 protein-altering or splice-affecting, 460 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,055, Silent 460, Frame Shift Del 326, Frame Shift Ins 53, Intron 51, Nonsense Mutation 49, In Frame Del 11, Splice Region 11, 3'UTR 9, 5'UTR 8, Splice Site 7, 5'Flank 6.

Variants (750 of 2,058; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758440592, CM055898, CM065946, COSV52932932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMS1 | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777706, CM136119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1922A>C p.K641T (on ENST00000288602 / NM_001374244.1; = p.K601T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs397507484, CM123147, CM140993, COSV56070869, COSV56115928; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 43/204 reads (21%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- COL4A3 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 48/356 reads (13%) | catalogued as rs769863513, CM052202, COSV67420825; ClinVar: likely pathogenic; called by muse, mutect2
- DAXX | c.1178del p.K393Rfs*135 | Frame Shift Del (DEL) | VAF 87/662 reads (13%) | catalogued as rs1359674497; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 62/270 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55525725, COSV55810858; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 76/446 reads (17%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.7219C>T p.R2407* | Nonsense Mutation (SNP) | VAF 65/303 reads (21%) | catalogued as rs398124471, CM073232, COSV56956936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 54/148 reads (36%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- RBCK1 | c.1054C>T p.R352* (on ENST00000356286 / NM_031229.4; = p.R310* on NM_006462.6) | Nonsense Mutation (SNP) | VAF 43/280 reads (15%) | catalogued as rs780854072, CM1313364, COSV100675876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4943G>A p.R1648H (on ENST00000303395 / NM_001202435.3; = p.R1637H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/447 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918622, CM000570; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 52/242 reads (21%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- VPS13B | c.5295G>T p.E1765D | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs780598553, CS125684, COSV100661925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762093692, COSV66066034; called by muse, mutect2, varscan2
- ABI3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs774034002, COSV56800665; called by muse, mutect2, varscan2
- ABTB2 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 100/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1475186898, COSV54395688; called by muse, mutect2, varscan2
- ACAN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 96/594 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs749720584, COSV61368045; called by muse, mutect2, varscan2
- ACOT7 | c.355G>A p.G119S (on ENST00000377855 / NM_181864.3; = p.G109S on NM_007274.4) | Missense Mutation (SNP) | VAF 88/471 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1257929224; called by muse, mutect2, varscan2
- ADAMTS2 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as COSV52393830; called by muse, mutect2, varscan2
- ADAMTS2 | c.2191del p.R731Gfs*26 | Frame Shift Del (DEL) | VAF 56/310 reads (18%) | catalogued as COSV52364596; called by mutect2, pindel, varscan2
- ADAMTS5 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176252; called by muse, mutect2, varscan2
- ADCY10 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373573088; called by muse, mutect2, varscan2
- ADGRB1 | c.4168G>A p.A1390T | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1239694222; called by muse, mutect2, varscan2
- ADGRF5 | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1254299103; called by muse, mutect2, varscan2
- ADGRL1 | c.2453C>A p.T818N (on ENST00000340736 / NM_001008701.3; = p.T813N on NM_014921.5) | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1187677025; called by muse, mutect2, varscan2
- ADRA1A | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 82/538 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52368465; called by muse, mutect2, varscan2
- AFAP1L2 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 93/451 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs776740763; called by muse, mutect2
- AGBL2 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs748126466; called by muse, mutect2, varscan2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 85/460 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- AKNAD1 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs370337411; called by muse, varscan2
- ALOX15 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 93/419 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1473044691; called by muse, mutect2, varscan2
- ALPK3 | c.4313C>T p.S1438L | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775335205, COSV51930604; called by muse, mutect2, varscan2
- AMFR | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs747167232; called by muse, mutect2, varscan2
- AMPH | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342210; called by muse, mutect2, varscan2
- ANGPTL6 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 74/420 reads (18%) | catalogued as rs201518909; called by muse, mutect2, varscan2
- ANKRD17 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770504687, COSV58216064; called by muse, mutect2, varscan2
- ANKRD18B | c.853del p.R285Efs*4 | Frame Shift Del (DEL) | VAF 29/168 reads (17%) | catalogued as rs755445457; called by mutect2, varscan2
- ANKRD6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs200814043; called by muse, varscan2
- ANO9 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs542936963, COSV60448403; called by muse, mutect2, varscan2
- ANTXR1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV58019953; called by muse, mutect2, varscan2
- AP002748.5 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1368997318; called by muse, mutect2, varscan2
- AP3M2 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs770525839; called by muse, mutect2, varscan2
- APC | c.3242G>A p.S1081N | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs374380039, COSV57399738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOE | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 84/482 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as rs947015878, COSV99376338; called by muse, mutect2, varscan2
- APTX | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs762632610; called by muse, mutect2, varscan2
- AQP5 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 95/435 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52231082; called by muse, mutect2, varscan2
- AQP8 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1407897720; called by muse, mutect2, varscan2
- AR | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as rs751758551; called by muse, mutect2, varscan2
- ARHGAP23 | c.2131G>A p.G711S | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.409); catalogued as rs1254539950; called by muse, mutect2, varscan2
- ARHGAP24 | c.136del p.D46Ifs*42 | Frame Shift Del (DEL) | VAF 56/342 reads (16%) | catalogued as COSV67846950; called by mutect2, pindel, varscan2
- ARHGAP26 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1433108180; called by muse, mutect2, varscan2
- ARHGEF7 | c.67dup p.T23Nfs*86 (on ENST00000375741 / NM_001113511.2; = p.T23Nfs*65 on NM_145735.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 66/354 reads (19%) | catalogued as rs754827718; called by mutect2, varscan2
- ARSJ | c.1292del p.N431Mfs*86 | Frame Shift Del (DEL) | VAF 74/372 reads (20%) | catalogued as rs1562327720; called by mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 43/340 reads (13%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 51/292 reads (17%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPHD2 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 102/481 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53218932; called by muse, mutect2, varscan2
- ASTN2 | c.2683T>C p.S895P (on ENST00000313400 / NM_001365069.1; = p.S844P on NM_014010.5) | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV57774733; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 78/481 reads (16%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ATAD2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs200021152; called by muse, mutect2, varscan2
- ATCAY | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs770582696, COSV100008582; called by muse, mutect2, varscan2
- ATG3 | c.342A>G p.T114= | Splice Region (SNP) | VAF 36/239 reads (15%) | catalogued as rs769027182; called by muse, varscan2
- ATN1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs782316240; called by muse, mutect2, varscan2
- ATP2A3 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765464068; called by muse, mutect2, varscan2
- ATP6V1F | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs145784230; called by muse, mutect2, varscan2
- ATP9B | c.1032T>C p.G344= | Splice Region (SNP) | VAF 35/200 reads (18%) | catalogued as COSV56957712; called by muse, mutect2, varscan2
- ATXN1 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs377356058; called by muse, mutect2, varscan2
- ATXN2L | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100294693; called by muse, mutect2, varscan2
- ATXN7 | c.2213G>A p.C738Y | Missense Mutation (SNP) | VAF 69/477 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1048571039; called by muse, mutect2, varscan2
- ATXN7L1 | c.2547G>T p.Q849H | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as rs1487481516, COSV66300450; called by muse, mutect2, varscan2
- AXIN1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 51/290 reads (18%) | catalogued as COSV51995526; called by muse, mutect2, varscan2
- B3GNT6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 97/603 reads (16%) | catalogued as rs1555027670; called by muse, mutect2, varscan2
- B3GNT9 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531342; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 44/307 reads (14%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BACH2 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57600126; called by muse, mutect2, varscan2
- BAIAP2 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs764303213, COSV58373796; called by muse, mutect2, varscan2
- BAIAP2L2 | c.770del p.P257Rfs*31 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | catalogued as rs1402946746; called by mutect2, pindel, varscan2
- BARD1 | c.1418A>C p.H473P | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176328026, COSV53612807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as rs772845446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBOX1 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV54193858; called by muse, mutect2, varscan2
- BCAS2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 37/219 reads (17%) | catalogued as rs781038404; called by muse, mutect2, varscan2
- BCKDK | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs781670286; called by muse, mutect2, varscan2
- BCS1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 84/482 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754414354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 62/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs781925980; called by muse, mutect2, varscan2
- BEND5 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65718687; called by muse, mutect2, varscan2
- BIRC6 | c.5488C>T p.R1830W | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70204050; called by muse, mutect2, varscan2
- BIRC6 | c.7319C>T p.A2440V | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as rs1298167873; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 48/300 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOD1L2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV101649296; called by muse, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 56/299 reads (19%) | catalogued as rs782133829; called by mutect2, varscan2
- BSN | c.9338G>A p.R3113H | Missense Mutation (SNP) | VAF 112/559 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs140240631; called by muse, mutect2, varscan2
- BTN3A3 | c.650del p.G217Vfs*74 | Frame Shift Del (DEL) | VAF 64/517 reads (12%) | catalogued as rs1387186083; called by mutect2, pindel, varscan2
- C4orf50 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 87/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423092488; called by muse, mutect2, varscan2
- C6orf132 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1275712359; called by muse, varscan2
- CACTIN | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 92/487 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs889092455, COSV50269608; called by muse, mutect2, varscan2
- CALCOCO1 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV100017509; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 64/306 reads (21%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAPN2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 85/461 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs746607443; called by muse, mutect2, varscan2
- CAPN6 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs760708333; called by muse, mutect2, varscan2
- CAPNS1 | c.242del p.P81Rfs*41 | Frame Shift Del (DEL) | VAF 97/332 reads (29%) | catalogued as COSV55822800; called by mutect2, pindel, varscan2
- CARNS1 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1268865987; called by muse, mutect2, varscan2
- CBX2 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 129/524 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782480335, COSV53969493; called by muse, mutect2, varscan2
- CCDC149 | c.1002dup p.L335Ifs*39 (on ENST00000635206 / NM_001330643.2; = p.L335Ifs*28 on NM_173463.5) | Frame Shift Ins (INS) | VAF 44/232 reads (19%) | catalogued as rs1478034807; called by mutect2, varscan2
- CCDC168 | c.15500C>T p.S5167L | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs555882008, COSV59420393; called by muse, varscan2
- CCDC17 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs746935513, COSV100601957; called by muse, mutect2, varscan2
- CCDC185 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as rs138878151, COSV64820216, COSV64820505; called by muse, mutect2, varscan2
- CCDC42 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 115/552 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs142451736; called by muse, mutect2, varscan2
- CCDC6 | c.44del p.G15Afs*59 | Frame Shift Del (DEL) | VAF 79/511 reads (15%) | catalogued as COSV99569582; called by mutect2, pindel, varscan2
- CCDC62 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs755321849; called by muse, mutect2, varscan2
- CCDC9 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1390076894; called by muse, mutect2, varscan2
- CCR1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs181920971; called by muse, mutect2, varscan2
- CD109 | c.743del p.G248Vfs*13 | Frame Shift Del (DEL) | VAF 30/273 reads (11%) | catalogued as COSV99753404; called by mutect2, pindel, varscan2
- CDC42BPG | c.3784G>T p.A1262S | Missense Mutation (SNP) | VAF 112/605 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as rs1410637516; called by muse, mutect2, varscan2
- CDH15 | c.1162del p.A388Hfs*89 | Frame Shift Del (DEL) | VAF 111/587 reads (19%) | catalogued as COSV99228980; called by mutect2, pindel, varscan2
- CDH17 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 69/420 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.194); catalogued as rs746585967; called by muse, mutect2, varscan2
- CDH4 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as rs888923510; called by muse, mutect2, varscan2
- CDHR2 | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 111/370 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV56134667; called by muse, varscan2
- CDK11A | c.1148C>T p.T383M (on ENST00000378633 / NM_001313896.2; = p.T380M on NM_024011.4) | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs538694157; called by muse, mutect2, varscan2
- CELF4 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV58450625; called by muse, mutect2, varscan2
- CELSR3 | c.4835G>A p.R1612Q | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.294); catalogued as rs373621912; called by muse, mutect2, varscan2
- CEP128 | c.1637T>C p.L546S | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141072132; called by muse, mutect2, varscan2
- CEP170B | c.4730C>T p.P1577L (on ENST00000453495; = p.P1506L on NM_015005.3) | Missense Mutation (SNP) | VAF 95/427 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as rs769122597; called by muse, mutect2, varscan2
- CEP192 | c.5402G>A p.R1801Q | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs753603607, COSV58067415; called by muse, mutect2, varscan2
- CEP192 | c.7361G>A p.G2454E | Missense Mutation (SNP) | VAF 84/528 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1359674784; called by muse, mutect2
- CEP97 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs570855126; called by muse, varscan2
- CFAP157 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs866067906, COSV58852132; called by muse, mutect2, varscan2
- CFAP410 | c.441_444del p.E148Afs*13 | Frame Shift Del (DEL) | VAF 98/548 reads (18%) | catalogued as rs756970705; called by mutect2, pindel, varscan2
- CFAP47 | c.1511T>C p.L504S | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as rs1245796900; called by muse, varscan2
- CFAP65 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 138/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377355595; called by muse, mutect2, varscan2
- CHD3 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs759303159; called by muse, mutect2, varscan2
- CHEK2 | c.761T>C p.V254A (on ENST00000382580 / NM_001005735.2; = p.V211A on NM_007194.4) | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.094); catalogued as CD160108; called by muse, mutect2, varscan2
- CHRD | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs750433253, COSV52607354; called by muse, mutect2, varscan2
- CHRD | c.2279C>A p.P760H | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369623177, COSV99200765; called by muse, mutect2, varscan2
- CHRNB2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201393088, COSV100872615; called by muse, mutect2, varscan2
- CHSY3 | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 61/514 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV59284700; called by muse, mutect2, varscan2
- CIITA | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 95/529 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs199476070; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CLIC6 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 130/632 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs1454173983; called by muse, mutect2, varscan2
- CLINT1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 127/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764235760, COSV99753388; called by muse, mutect2, varscan2
- CLNK | c.80del p.N27Tfs*17 | Frame Shift Del (DEL) | VAF 57/314 reads (18%) | catalogued as rs1430451531; called by mutect2, pindel, varscan2
- CLTB | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as rs770160355; called by muse, mutect2, varscan2
- CNIH3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs187848266, COSV99685839; called by muse, mutect2, varscan2
- CNNM1 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs201507104; called by muse, mutect2, varscan2
- CNR1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 67/415 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs267601156; called by muse, mutect2, varscan2
- COA4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 91/520 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs146693705; called by muse, mutect2, varscan2
- COL19A1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 55/278 reads (20%) | catalogued as rs759896577, COSV100506480, COSV59573575; called by muse, mutect2, varscan2
- COL21A1 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV55176092; called by muse, mutect2, varscan2
- COL22A1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 97/594 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401231530; called by muse, mutect2, varscan2
- COL5A3 | c.2999del p.P1000Qfs*144 | Frame Shift Del (DEL) | VAF 60/310 reads (19%) | catalogued as rs760926657; called by mutect2, pindel, varscan2
- COL6A6 | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs368469507; called by muse, mutect2, varscan2
- COLGALT2 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 80/437 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780516386, COSV62300903; called by muse, mutect2, varscan2
- CPEB2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs1162407034, COSV52592867; called by muse, mutect2, varscan2
- CPED1 | c.2778del p.K926Nfs*6 | Frame Shift Del (DEL) | VAF 55/314 reads (18%) | catalogued as rs777945397; called by mutect2, pindel, varscan2
- CPNE2 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51963022; called by muse, mutect2, varscan2
- CPT1C | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs149943122; called by muse, mutect2, varscan2
- CROCC2 | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.389); catalogued as rs568085134; called by muse, mutect2, varscan2
- CRTC2 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747047912, COSV57841827, COSV57846253; called by muse, mutect2, varscan2
- CRYBB3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 93/453 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772868069, COSV99309045; called by muse, mutect2, varscan2
- CSAD | c.649G>T p.G217W (on ENST00000444623 / NM_001244705.2; = p.G244W on NM_015989.5) | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914715; called by muse, mutect2, varscan2
- CSGALNACT1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1029503064; called by muse, mutect2, varscan2
- CSMD2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200867038, COSV99585859; called by muse, mutect2, varscan2
- CSPG4 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as rs1408308659; called by muse, varscan2
- CSRP2 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 100/571 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60702058; called by muse, mutect2, varscan2
- CTBP1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 115/634 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764862588, COSV52071459; called by muse, mutect2, varscan2
- CTSG | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53534971; called by muse, mutect2, varscan2
- CTU1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 92/466 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV70292214; called by muse, mutect2, varscan2
- CUL7 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs757730802, COSV54815917; called by muse, mutect2, varscan2
- CYP1A2 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV59659790; called by mutect2, varscan2
- CYP2C18 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749885860; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | catalogued as rs1467050790; called by mutect2, pindel, varscan2
- CYP7B1 | c.1253T>G p.F418C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59590705; called by muse, mutect2, varscan2
- DAGLB | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1231346406; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 25/198 reads (13%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DCAF12 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs779607013; called by muse, mutect2, varscan2
- DCC | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs748884864, COSV59113651; called by muse, mutect2, varscan2
- DCLK1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55186866; called by muse, mutect2, varscan2
- DDX18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs187810830; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 40/281 reads (14%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DIO3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 115/579 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1312207192; called by muse, mutect2, varscan2
- DLC1 | c.1529C>T p.A510V (on ENST00000276297 / NM_001348081.2; = p.A73V on NM_006094.5) | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1064795440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 79/453 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs531588076; called by muse, mutect2, varscan2
- DLGAP2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 87/526 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as rs754396312, COSV70094193; called by muse, mutect2, varscan2
- DMD | c.5239G>A p.D1747N | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63745956; called by muse, mutect2, varscan2
- DNAH3 | c.8457C>T p.S2819= | Splice Region (SNP) | VAF 45/240 reads (19%) | catalogued as rs754426138, COSV54509182; called by muse, mutect2, varscan2
- DNAH3 | c.3287T>A p.I1096N | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99764731; called by muse, mutect2, varscan2
- DNM2 | c.2180A>G p.H727R (on ENST00000355667 / NM_001005360.3; = p.H723R on NM_004945.3) | Missense Mutation (SNP) | VAF 89/462 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs1334633159; called by muse, mutect2, varscan2
- DOCK10 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1305763186, COSV51420167; called by muse, varscan2
- DOCK5 | c.1735del p.M579Wfs*8 | Frame Shift Del (DEL) | VAF 32/218 reads (15%) | catalogued as rs1282784562; called by mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 21/220 reads (10%) | catalogued as rs1239294263; called by pindel, varscan2
- DOCK6 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | catalogued as rs936266747; called by muse, varscan2
- DOCK6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as COSV53917121; called by muse, varscan2
- DOT1L | c.2925del p.F975Lfs*93 | Frame Shift Del (DEL) | VAF 120/628 reads (19%) | catalogued as COSV67112023; called by mutect2, pindel, varscan2
- DPEP2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1248948278; called by muse, mutect2, varscan2
- DPF2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 69/395 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1467910075; called by muse, mutect2, varscan2
- DPP9 | c.2033A>G p.D678G (on ENST00000598800; = p.D707G on NM_139159.5) | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs753225029; called by muse, mutect2, varscan2
- DPP9 | c.40G>A p.A14T (on ENST00000598800; = p.A43T on NM_139159.5) | Missense Mutation (SNP) | VAF 118/577 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs558641911, COSV53592216; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DSCAML1 | c.5854C>T p.R1952W (on ENST00000321322; = p.R1892W on NM_020693.4) | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201027576, COSV58387248; called by muse, mutect2, varscan2
- DTHD1 | c.164dup p.N55Kfs*2 (on ENST00000456874; = p.N180Kfs*2 on NM_001170700.3) | Frame Shift Ins (INS) | VAF 44/224 reads (20%) | catalogued as rs34134908; called by mutect2, varscan2
- DUOX2 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 57/406 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs750364813, COSV66534315; called by muse, mutect2, varscan2
- DYM | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as rs1177548570, COSV53988938; called by muse, mutect2, varscan2
- DYNC2I1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV101337729; called by muse, mutect2, varscan2
- EBF3 | c.1489G>A p.A497T (on ENST00000355311 / NM_001375392.1; = p.A488T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/492 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs138447716, COSV100799028; called by muse, mutect2, varscan2
- ECPAS | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52194898; called by muse, varscan2
- EFCAB1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 83/492 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753689165, COSV50617909; called by muse, varscan2
- EFR3B | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs894458724; called by muse, mutect2, varscan2
- EGFR | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775695605, COSV51776216, COSV99296123; called by muse, mutect2, varscan2
- EIF3G | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV53451288; called by muse, mutect2, varscan2
- EML6 | c.5298del p.K1766Nfs*20 | Frame Shift Del (DEL) | VAF 66/329 reads (20%) | catalogued as rs869287646; called by mutect2, pindel, varscan2
- ENAH | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1261936433; called by muse, mutect2, varscan2
- EPB41L2 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1174372686, COSV61356877; called by muse, mutect2, varscan2
- EPC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433910452, COSV53923041; called by muse, mutect2, varscan2
- EPHA10 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 103/479 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs781544726, COSV60402475; called by muse, mutect2, varscan2
- EPHA3 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 54/387 reads (14%) | catalogued as rs1472226095, COSV60719015, COSV99069576; called by muse, varscan2
- EPHA7 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 79/466 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65170401; called by muse, mutect2, varscan2
- EPPK1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 129/849 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782045792; called by muse, mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 72/407 reads (18%) | catalogued as rs781559768; called by pindel, varscan2
- ESPN | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 68/466 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs1449515084; called by muse, varscan2
- ETNK2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 104/491 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1420802320, COSV99689654; called by muse, mutect2, varscan2
- EVPL | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1309525993; called by muse, varscan2
- EYA1 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503047, COSV58175577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1044216762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZHIP | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 126/377 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1006910285, COSV57955307; called by muse, mutect2, varscan2
- FAM120A | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.552); catalogued as rs765247935; called by muse, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 31/210 reads (15%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM13C | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1304753095, COSV53245191; called by muse, mutect2, varscan2
- FAM171A2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs548562099; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 127/601 reads (21%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM47C | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.687); catalogued as rs1556332293, COSV100792488; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.12902G>A p.R4301H | Missense Mutation (SNP) | VAF 85/549 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147369556; called by muse, mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 67/448 reads (15%) | catalogued as rs747011618; called by mutect2, varscan2
- FBLIM1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 133/655 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748856645, COSV60028625; called by muse, mutect2, varscan2
- FBLN2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 102/505 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs371872562; called by muse, mutect2, varscan2
- FBRSL1 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 96/539 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs1233605862; called by muse, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, varscan2
- FBXO33 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 34/273 reads (12%) | catalogued as COSV53233777; called by muse, mutect2, varscan2
- FBXO38 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 49/355 reads (14%) | catalogued as rs753065225; called by muse, mutect2, varscan2
- FGD6 | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269009624, COSV59696433; called by muse, mutect2, varscan2
- FLG | c.7159G>A p.G2387R | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs775764952, COSV100911672; called by muse, mutect2, varscan2
- FMO4 | c.1558del p.A520Hfs*18 | Frame Shift Del (DEL) | VAF 67/436 reads (15%) | catalogued as rs770011693, COSV100882071; called by mutect2, pindel, varscan2
- FNDC1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 121/690 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as rs771247742, COSV51935468; called by muse, mutect2, varscan2
- FOXF1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 104/548 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286748; called by muse, varscan2
- FOXK1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 105/508 reads (21%) | catalogued as rs1397177767, COSV61065914; called by muse, varscan2
- FRMD6 | c.1099C>T p.R367W (on ENST00000344768 / NM_001267046.2; = p.R359W on NM_152330.4) | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs35856363, COSV100655572; called by muse, mutect2, varscan2
- FUT4 | c.1158C>G p.F386L | Missense Mutation (SNP) | VAF 89/507 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62469505; called by muse, mutect2, varscan2
- FUT8 | c.1417C>T p.R473* (on ENST00000360689 / NM_001371534.1; = p.R310* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 41/206 reads (20%) | catalogued as COSV61281308; called by muse, mutect2, varscan2
- FXR1 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV59766678; called by muse, mutect2, varscan2
- GABRB1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 76/496 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54986839, COSV54988273, COSV55000495; called by muse, mutect2, varscan2
- GABRP | c.775T>G p.L259V | Missense Mutation (SNP) | VAF 67/440 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs747925903; called by mutect2, varscan2
- GAREM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422190759, COSV52505694; called by muse, mutect2, varscan2
- GCAT | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142242726; called by muse, mutect2, varscan2
- GFY | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1429686267; called by muse, mutect2, varscan2
- GGT7 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 93/499 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs34687214; called by muse, mutect2, varscan2
- GIMAP5 | c.890del p.F297Sfs*30 | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | catalogued as rs774162620, COSV57529761, COSV57529909; called by mutect2, varscan2
- GLI3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 79/410 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760174184, COSV67885478, COSV67885819; called by muse, mutect2, varscan2
- GNAI2 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 107/526 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553703488; called by muse, mutect2, varscan2
- GNAS | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 90/494 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV100005342; called by muse, mutect2, varscan2
- GNAS | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as CM152407; called by muse, mutect2, varscan2
- GNB1L | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61548607; called by muse, varscan2
- GPM6A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.224); catalogued as COSV99703150; called by muse, mutect2, varscan2
- GPR137 | c.1091del p.P364Lfs*? | Frame Shift Del (DEL) | VAF 67/400 reads (17%) | catalogued as COSV100464157, COSV57402216; called by mutect2, varscan2
- GPR155 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1559113891; called by muse, mutect2, varscan2
- GPR155 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 49/289 reads (17%) | catalogued as rs375197307; called by muse, mutect2, varscan2
- GPR25 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 80/511 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as rs752404907; called by muse, mutect2, varscan2
- GPR68 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.864); catalogued as rs1448146948, COSV53176500; called by muse, mutect2, varscan2
- GPRIN1 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 95/590 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1404322981; called by muse, mutect2, varscan2
- GRIA1 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 48/206 reads (23%) | catalogued as COSV53630561; called by muse, varscan2
- GRIN2B | c.3505G>A p.G1169R | Missense Mutation (SNP) | VAF 77/467 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.754); catalogued as rs777639067, COSV101663161, COSV74207066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 74/635 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV51291708; called by muse, mutect2, varscan2
- GRM4 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 77/492 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1338131065, COSV65212346; called by muse, mutect2, varscan2
- GRN | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs757831826, COSV50007966, COSV50008726; called by muse, mutect2, varscan2
- GTDC1 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763722216; called by muse, mutect2, varscan2
- GYS2 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as rs886049155; ClinVar: uncertain significance; called by muse, varscan2
- H4C12 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs1314153326; called by muse, mutect2, varscan2
- HACE1 | c.1793del p.R598Lfs*11 | Frame Shift Del (DEL) | VAF 32/268 reads (12%) | catalogued as COSV53499381; called by mutect2, pindel, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 44/206 reads (21%) | catalogued as rs748396956; called by mutect2, varscan2
- HBM | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 113/657 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774748950; called by muse, mutect2, varscan2
- HCFC2 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV99983114; called by muse, mutect2, varscan2
- HDAC5 | c.695del p.P232Lfs*32 | Frame Shift Del (DEL) | VAF 65/366 reads (18%) | catalogued as COSV56820100; called by mutect2, pindel, varscan2
- HDDC3 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs868073323; called by muse, mutect2, varscan2
- HEATR6 | c.1311del p.V438Ffs*24 | Frame Shift Del (DEL) | VAF 54/329 reads (16%) | catalogued as rs748699945, COSV51743560; called by mutect2, varscan2
- HECTD4 | c.4645C>T p.R1549C | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs776696918, COSV101106554; called by muse, mutect2, varscan2
- HEPACAM | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs549252759, COSV53430756, COSV53432474; called by muse, mutect2, varscan2
- HERC1 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371163845; called by muse, mutect2, varscan2
- HERC2 | c.11684G>A p.R3895H | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as rs945751718; called by muse, mutect2, varscan2
- HERC2 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 80/493 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.416); catalogued as rs147116947; called by muse, mutect2, varscan2
- HIF3A | c.1880G>A p.S627N (on ENST00000377670 / NM_152795.4; = p.S558N on NM_022462.4) | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as COSV99355912; called by muse, varscan2
- HIP1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 69/477 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs138838220, COSV61183378; called by muse, mutect2, varscan2
- HIPK2 | c.3022T>C p.S1008P | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs752980431; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 44/362 reads (12%) | catalogued as COSV50007394; called by muse, mutect2, varscan2
- HIVEP2 | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1424214061; called by muse, mutect2, varscan2
- HK1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 84/554 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1332719473; called by muse, mutect2
- HMGCS2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767236647, COSV65567358; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 56/371 reads (15%) | catalogued as COSV99670288; called by mutect2, pindel, varscan2
- HOXC10 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.035); catalogued as rs878883787, COSV57727010; called by muse, varscan2
- HOXD12 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs779274101, COSV66832344; called by muse, mutect2, varscan2
- HRNR | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 91/491 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs765957331, COSV100913936; called by muse, mutect2, varscan2
- HS1BP3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs760156212, COSV58311926; called by muse, mutect2, varscan2
- HS6ST3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.251); catalogued as rs1268310394, COSV65009296; called by muse, mutect2, varscan2
- HSPA12B | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs1267552512, COSV53924280; called by muse, mutect2, varscan2
- HTR1A | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1427602417; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- HUS1B | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV57871685; called by muse, mutect2, varscan2
- HUWE1 | c.7561C>T p.R2521C | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1221267143, COSV53335206; called by muse, varscan2
- IDE | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs764826071; called by muse, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 87/441 reads (20%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IGDCC3 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1209689800; called by muse, mutect2, varscan2
- IL1R2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145651311, COSV100208321; called by muse, mutect2, varscan2
- IL1RL1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.701); catalogued as COSV52115064; called by muse, mutect2, varscan2
- INCENP | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV53921519; called by muse, mutect2, varscan2
- INF2 | c.1864del p.R622Gfs*18 | Frame Shift Del (DEL) | VAF 70/436 reads (16%) | catalogued as rs1459726028; called by mutect2, pindel, varscan2
- INPPL1 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1565381470; called by muse, mutect2, varscan2
- INPPL1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200057735; called by muse, varscan2
- INPPL1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293622519, COSV53354767, COSV53358764, COSV99996721; called by muse, mutect2, varscan2
- INTS6L | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs143980255, COSV66085332; called by muse, mutect2, varscan2
- IRF2BP1 | c.367del p.L123Cfs*39 | Frame Shift Del (DEL) | VAF 108/617 reads (18%) | catalogued as COSV56195278; called by pindel, varscan2
- IRS2 | c.3265G>C p.A1089P | Missense Mutation (SNP) | VAF 105/616 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs780127725, COSV65477933; called by muse, mutect2, varscan2
- IRX2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 108/627 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.044); catalogued as rs1260443534, COSV57414036; called by muse, mutect2, varscan2
- ITGAE | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1245613648; called by muse, mutect2, varscan2
- ITGB8 | c.*5del | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | catalogued as rs770665724; called by mutect2, pindel, varscan2
- ITK | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70060494; called by muse, mutect2, varscan2
- JAG2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 77/464 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389623306; called by muse, varscan2
- JAM3 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs762709121, COSV54451756; called by muse, mutect2, varscan2
- JAM3 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs367727226; called by muse, mutect2, varscan2
- KATNIP | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 76/402 reads (19%) | catalogued as rs150515359; called by muse, mutect2, varscan2
- KCNB2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 81/557 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781046739, COSV73049383; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 74/411 reads (18%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNG4 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 103/536 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs371214019; called by muse, mutect2, varscan2
- KCNK5 | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 83/541 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63989083; called by muse, mutect2, varscan2
- KCNMA1 | c.3584C>T p.S1195L (on ENST00000286628 / NM_001161352.2; = p.S1137L on NM_002247.4) | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs202024249, COSV54296032; called by muse, mutect2, varscan2
- KCNS2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 69/499 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1480950741, COSV99750882; called by muse, mutect2, varscan2
- KCTD15 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs748743699; called by muse, mutect2, varscan2
- KDM3A | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 70/379 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs754148984, COSV57225727; called by muse, mutect2, varscan2
- KDM4B | c.2638G>A p.V880M | Missense Mutation (SNP) | VAF 87/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1268282336; called by muse, varscan2
- KDM6A | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs763592177, COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by muse, mutect2, varscan2
- KDM6A | c.3502G>T p.V1168F | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65045879; called by muse, mutect2, varscan2
- KIAA1549L | c.949G>A p.A317T (on ENST00000321505; = p.A614T on NM_012194.3) | Missense Mutation (SNP) | VAF 98/415 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1217319745; called by muse, mutect2, varscan2
- KIAA1549L | c.4869G>A p.P1623= (on ENST00000321505; = p.P1920= on NM_012194.3) | Splice Region (SNP) | VAF 32/210 reads (15%) | catalogued as rs771446533, COSV58586351; called by muse, mutect2, varscan2
- KIF15 | c.1354T>A p.F452I | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as rs936284136; called by muse, mutect2, varscan2
- KIF18B | c.1178dup p.G394Rfs*32 (on ENST00000593135 / NM_001265577.2; = p.G394Rfs*44 on NM_001264573.2) | Frame Shift Ins (INS) | VAF 75/401 reads (19%) | catalogued as rs1347932473; called by mutect2, pindel, varscan2
- KIF1A | c.4790C>T p.T1597M (on ENST00000320389 / NM_001379639.1; = p.T1589M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1468911667; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 41/246 reads (17%) | catalogued as rs777890702; called by pindel, varscan2
- KIFC2 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 74/518 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs184801242; called by muse, mutect2, varscan2
- KIRREL2 | c.2070del p.F691Sfs*40 | Frame Shift Del (DEL) | VAF 95/504 reads (19%) | catalogued as COSV99383816; called by mutect2, pindel, varscan2
- KLF14 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 92/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1554470843; called by muse, varscan2
- KLF15 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as rs753392896, COSV99955064; called by muse, varscan2
- KLHDC7B | c.488del p.G163Afs*83 (on ENST00000395676; = p.G804Afs*83 on NM_138433.5) | Frame Shift Del (DEL) | VAF 106/566 reads (19%) | catalogued as rs1435543889; called by mutect2, pindel, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 27/172 reads (16%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2A | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1555035714, COSV63288980, COSV63291142; called by muse, mutect2, varscan2
- KMT2A | c.10161G>T p.Q3387H | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1462963975; called by muse, mutect2, varscan2
- KMT2C | c.14530G>A p.A4844T | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469176725, COSV51277101; called by muse, mutect2, varscan2
- KMT2C | c.6865C>T p.R2289C | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs764025360; called by muse, mutect2, varscan2
- KMT2D | c.8341C>G p.P2781A | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1434600307, COSV104396936, COSV56451437; called by muse, mutect2, varscan2
- KNDC1 | c.4094G>T p.G1365V | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV58841041; called by muse, mutect2, varscan2
- KNL1 | c.3728T>C p.L1243P (on ENST00000346991 / NM_170589.5; = p.L1217P on NM_144508.5) | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs758895510; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | catalogued as rs761148574; called by mutect2, varscan2
- KRTAP19-5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs112006874, COSV61858873; called by muse, mutect2, varscan2
- KRTAP4-9 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 89/524 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs1231970295; called by muse, mutect2, varscan2
- KSR2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs548971268, COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMA4 | c.4246G>T p.G1416* (on ENST00000230538 / NM_001105206.3; = p.G1409* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/309 reads (14%) | catalogued as COSV57895500; called by muse, mutect2, varscan2
- LAMA5 | c.5800C>T p.R1934C | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs750315166; called by muse, mutect2, varscan2
- LGALS3BP | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 76/468 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs377712591; called by muse, mutect2, varscan2
- LHX9 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs768603459; called by muse, mutect2, varscan2
- LILRA2 | c.1355G>A p.R452H (on ENST00000391738 / NM_001130917.3; = p.R435H on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/591 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs199988092, COSV52191718; called by muse, mutect2, varscan2
- LMF2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 109/552 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141701845; called by muse, mutect2, varscan2
- LMNA | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 105/471 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV61541879; called by muse, mutect2, varscan2
- LMNTD2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 97/534 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752614516; called by muse, mutect2, varscan2
- LMOD3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376653017, COSV70456400; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 20/207 reads (10%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRFN2 | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 92/647 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs150683269; called by muse, mutect2, varscan2
- LRIT2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1445101374, COSV64518298; called by muse, mutect2, varscan2
- LRP12 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371335155; called by muse, mutect2, varscan2
- LRP1B | c.12673G>T p.G4225* | Nonsense Mutation (SNP) | VAF 51/291 reads (18%) | catalogued as COSV67195038; called by muse, mutect2, varscan2
- LRP5 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 96/458 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1394958801; called by muse, mutect2, varscan2
- LRRC19 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs199558016; called by muse, mutect2, varscan2
- LRRC29 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1438669806, COSV99050805; called by muse, varscan2
- LRRC9 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1175476030, COSV99580562; called by muse, mutect2, varscan2
- LRRCC1 | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1259727719; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs745692987; called by mutect2, varscan2
- LTBP4 | c.4201C>A p.L1401M (on ENST00000308370 / NM_001042544.1; = p.L1364M on NM_003573.2) | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as rs1052471685; called by muse, mutect2, varscan2
- LYSMD2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769063670; called by muse, mutect2, varscan2
- LZTS1 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 97/567 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as rs768951518; called by muse, mutect2, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 52/385 reads (14%) | catalogued as rs775539898; called by mutect2, pindel, varscan2
- MAG | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1032956121, COSV62698909; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 38/189 reads (20%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K21 | c.2201C>A p.A734D | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64041723; called by muse, mutect2, varscan2
- MAP4K5 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 66/413 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99184799; called by muse, mutect2, varscan2
- MAP7D1 | c.1252_1254del p.K418del | In Frame Del (DEL) | VAF 65/301 reads (22%) | catalogued as rs752518838; called by pindel, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK1IP1L | c.595T>C p.W199R | Missense Mutation (SNP) | VAF 82/489 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as rs763634125; called by muse, mutect2, varscan2
- MAPKBP1 | c.3037C>T p.H1013Y (on ENST00000456763 / NM_001128608.2; = p.H1007Y on NM_014994.3) | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1244670976; called by muse, mutect2, varscan2
- MARS1 | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs780028144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARVELD3 | c.948dup p.Y317Vfs*22 | Frame Shift Ins (INS) | VAF 53/321 reads (17%) | catalogued as rs747980715; called by mutect2, varscan2
- MBIP | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.199); catalogued as rs200960426; called by muse, mutect2, varscan2
- MCHR1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 95/580 reads (16%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as rs771256039; called by muse, mutect2, varscan2
- MCMBP | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs755914490; called by muse, mutect2, varscan2
- MEAK7 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs370281146; called by muse, mutect2, varscan2
- MED15 | c.2261G>A p.R754H (on ENST00000263205 / NM_001003891.3; = p.R714H on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs368856165; called by muse, mutect2, varscan2
- MED23 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 66/421 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1562373867; called by muse, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 101/547 reads (18%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MIB2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755453798; called by muse, varscan2
- MICU3 | c.803del p.N268Mfs*47 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as rs199759760; called by mutect2, varscan2
- MID1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1169366982, COSV58198773; called by muse, varscan2
- MINAR1 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV59583363, COSV59584062; called by muse, mutect2, varscan2
- MMP17 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV62180542; called by muse, mutect2, varscan2
- MMS22L | c.3011G>A p.G1004D | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452614379, COSV104390048, COSV51524201; called by muse, mutect2, varscan2
- MOGS | c.2293G>T p.A765S | Missense Mutation (SNP) | VAF 70/395 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1482002989; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs757379917; called by mutect2, varscan2
- MPP2 | c.487C>T p.R163C (on ENST00000461854 / NM_001278372.2; = p.R139C on NM_005374.5) | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757493946, COSV99290631; called by muse, mutect2, varscan2
- MRC2 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57640753, COSV57641679; called by muse, mutect2, varscan2
- MROH1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 65/510 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765665232, COSV58192057; called by muse, mutect2, varscan2
- MRPL53 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs968380682; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as rs779922206; called by mutect2, varscan2
- MS4A6A | c.562_563dup p.M189* | Frame Shift Ins (INS) | VAF 25/155 reads (16%) | catalogued as rs1565096834; called by mutect2, varscan2
- MSANTD1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1474075287, COSV101433714; called by muse, varscan2
- MSI1 | c.345del p.L116Cfs*3 | Frame Shift Del (DEL) | VAF 81/530 reads (15%) | catalogued as rs748469666; called by mutect2, pindel, varscan2
- MTA3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs768192257; called by muse, mutect2, varscan2
- MUC16 | c.36080G>A p.R12027Q | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs769222839, COSV67471709; called by muse, mutect2, varscan2
- MUC16 | c.6263C>T p.T2088I | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV101199974; called by muse, mutect2, varscan2
- MUC6 | c.7111C>T p.R2371C | Missense Mutation (SNP) | VAF 75/527 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1186646568, COSV59963310, COSV59963815; called by muse, mutect2, varscan2
- MYCBP2 | c.3850C>T p.P1284S (on ENST00000357337; = p.P1322S on NM_015057.5) | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62017074; called by muse, mutect2, varscan2
- MYCN | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 108/679 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV99808391; called by muse, mutect2, varscan2
- MYH7B | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 74/437 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771512439, COSV52685284; called by muse, mutect2, varscan2
- MYH9 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs376240562; called by muse, mutect2, varscan2
- MYO1F | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as CM090126; called by muse, mutect2, varscan2
- MYOM2 | c.107del p.K36Sfs*13 | Frame Shift Del (DEL) | VAF 59/407 reads (14%) | catalogued as rs1360158578; called by mutect2, pindel, varscan2
- MYT1L | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 70/440 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV67713140; called by muse, varscan2
- NAALADL2 | c.1554del p.N520Mfs*12 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs1478908176, COSV69154859; called by pindel, varscan2
- NAGLU | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 90/431 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894590, CM950832, COSV56795017; called by muse, mutect2, varscan2
- NAV2 | c.2458G>A p.A820T (on ENST00000396087 / NM_001244963.2; = p.A797T on NM_145117.5) | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140354139, COSV62320806; called by muse, mutect2, varscan2
- NBEA | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); catalogued as rs1348731685, COSV59779612; called by muse, mutect2, varscan2
- NCOR2 | c.4990C>A p.L1664M | Missense Mutation (SNP) | VAF 90/489 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV62292639; called by muse, mutect2, varscan2
- NDC1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1207224755, COSV52334729; called by muse, mutect2, varscan2
- NDN | c.94del p.V32Ffs*15 | Frame Shift Del (DEL) | VAF 48/350 reads (14%) | catalogued as rs1430155453; called by pindel, varscan2
- NDUFA10 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201798886; called by muse, mutect2, varscan2
- NEB | c.19081C>T p.R6361C | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs542275170; called by muse, mutect2, varscan2
- NEFM | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55335400; called by muse, mutect2, varscan2
- NEUROD1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 82/413 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV54549697; called by muse, varscan2
- NHLRC1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 104/586 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs368134036, COSV61481237; called by muse, mutect2, varscan2
- NID2 | c.1127del p.G376Afs*4 | Frame Shift Del (DEL) | VAF 48/317 reads (15%) | catalogued as COSV53499595; called by mutect2, pindel, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 77/574 reads (13%) | catalogued as rs745904099; called by mutect2, pindel, varscan2
- NLRP14 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205232; called by muse, varscan2
- NLRP14 | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1472653484; called by muse, mutect2, varscan2
- NLRP2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 88/444 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1165462336, COSV54756823; called by muse, mutect2, varscan2
- NMBR | c.768del p.K256Nfs*45 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | catalogued as rs1470345555; called by mutect2, pindel, varscan2
- NMUR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 94/501 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs777720090, COSV59404186; called by muse, mutect2, varscan2
- NOD1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565502191; called by muse, varscan2
- NOTCH1 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 98/517 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53043280, COSV53047338; called by muse, mutect2, varscan2
- NPNT | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV59753137; called by muse, varscan2
- NPR2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1481073248; called by muse, mutect2, varscan2
- NSD1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1215568879, COSV61775264; called by muse, mutect2, varscan2
- NSRP1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 27/228 reads (12%) | catalogued as rs374096765; called by muse, mutect2, varscan2
- NSUN5 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 106/586 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV53090867; called by muse, mutect2, varscan2
- NTNG1 | c.1429G>A p.G477R (on ENST00000370068 / NM_001113226.3; = p.G376R on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100903292; called by muse, mutect2, varscan2
- NUDCD3 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs953619201; called by muse, mutect2, varscan2
- NUP214 | c.6017C>T p.S2006L | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763033567; called by muse, mutect2, varscan2
- NUP98 | c.5111G>A p.R1704H (on ENST00000359171 / NM_001365126.1; = p.R1687H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs146194229, COSV100261384; called by muse, mutect2, varscan2
- NXF1 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs770860085; called by muse, mutect2, varscan2
- OLFM2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 118/546 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs765662180, COSV53428450; called by muse, mutect2, varscan2
- OR10K2 | c.788A>T p.Q263L | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV59222905; called by muse, mutect2, varscan2
- OR10W1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs910818427, COSV67720197; called by muse, mutect2, varscan2
- OR13D1 | c.526A>C p.M176L | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs891572864; called by muse, mutect2, varscan2
- OR4A15 | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 74/394 reads (19%) | catalogued as COSV59036704; called by muse, mutect2, varscan2
- OR4K14 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV59293272; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 55/368 reads (15%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR4Q3 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59179726; called by muse, mutect2, varscan2
- OR52E6 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.277); catalogued as rs1306204603; called by muse, mutect2, varscan2
- OR5H1 | c.921dup p.H308Tfs*3 | Frame Shift Ins (INS) | VAF 17/105 reads (16%) | catalogued as rs750155763; called by mutect2, varscan2
- OR9H1P | c.537del p.P181Hfs*12 | Frame Shift Del (DEL) | VAF 57/304 reads (19%) | catalogued as rs950040005; called by mutect2, pindel, varscan2
- OSBP2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs1478252504; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 60/443 reads (14%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- P3H2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748750473, COSV60017755, COSV60023143; called by muse, mutect2, varscan2
- PAQR4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 106/556 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748058094, COSV51893053; called by muse, varscan2
- PARP4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs758277432, COSV67964417; called by muse, mutect2, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 60/378 reads (16%) | catalogued as rs770881706; called by mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHA1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.436); catalogued as COSV65373700; called by muse, mutect2, varscan2
- PCDHA10 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 65/370 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.161); catalogued as COSV56481603; called by muse, mutect2, varscan2
- PCDHA7 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 126/695 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782561322, COSV65341561, COSV65345338; called by muse, mutect2, varscan2
- PCDHB11 | c.190del p.A64Lfs*16 | Frame Shift Del (DEL) | VAF 70/417 reads (17%) | catalogued as rs782500133; called by mutect2, pindel, varscan2
- PCDHB16 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1371346092, COSV53357605; called by muse, mutect2, varscan2
- PCDHB3 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50571022; called by muse, mutect2, varscan2
- PCDHB5 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV50647253; called by muse, mutect2, varscan2
- PCDHB6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 34/858 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs199646293, COSV50702544; called by muse, mutect2
- PCDHGA6 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 137/748 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1436738898; called by muse, mutect2, varscan2
- PCDHGB3 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 101/460 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs903944197, COSV53935008; called by muse, mutect2, varscan2
- PCNX1 | c.3604del p.C1202Vfs*4 | Frame Shift Del (DEL) | VAF 45/282 reads (16%) | catalogued as COSV99456874; called by mutect2, pindel, varscan2
- PCSK5 | c.3068G>A p.G1023E | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs748907371; called by muse, mutect2, varscan2
- PDCD10 | c.211del p.S71Afs*18 | Frame Shift Del (DEL) | VAF 28/221 reads (13%) | catalogued as CD143177; called by mutect2, pindel, varscan2
- PDE6C | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.669); catalogued as COSV65116630; called by muse, varscan2
- PDPN | c.41C>T p.A14V (on ENST00000621990; = p.A90V on NM_006474.4) | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV53848837; called by muse, mutect2, varscan2
- PDZRN4 | c.1687C>T p.R563* (on ENST00000402685 / NM_001164595.2; = p.R305* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 70/321 reads (22%) | catalogued as rs150680549, COSV54203393; called by muse, mutect2, varscan2
- PEAR1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 127/608 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs767863459; called by muse, mutect2, varscan2
- PEDS1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59014001; called by muse, mutect2, varscan2
- PGC | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs143935750; called by muse, mutect2, varscan2
- PHF21B | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs370081683; called by muse, mutect2, varscan2
- PHGR1 | c.175dup p.H59Pfs*28 | Frame Shift Ins (INS) | VAF 32/246 reads (13%) | catalogued as rs748850271; called by mutect2, varscan2
- PHLPP2 | c.3485G>A p.G1162D | Missense Mutation (SNP) | VAF 72/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567610334, COSV62424416; called by muse, mutect2, varscan2
- PICK1 | c.42C>T p.L14= | Splice Region (SNP) | VAF 49/284 reads (17%) | catalogued as rs149993932; called by muse, mutect2, varscan2
- PIGS | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371227096; called by muse, mutect2, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 67/361 reads (19%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PIK3R2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 84/473 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1365373370; called by muse, mutect2, varscan2
- PIK3R3 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs554826078, COSV53111455; called by muse, mutect2, varscan2
- PKD2 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs763864486; called by muse, mutect2, varscan2
- PKP3 | c.1390dup p.L464Pfs*224 | Frame Shift Ins (INS) | VAF 100/472 reads (21%) | catalogued as rs757594408; called by mutect2, varscan2
- PLCD4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs200972923; called by muse, mutect2, varscan2
- PLEC | c.9472C>T p.R3158W (on ENST00000322810 / NM_201380.4; = p.R3048W on NM_000445.5) | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs782202018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.4567G>A p.A1523T (on ENST00000322810 / NM_201380.4; = p.A1413T on NM_000445.5) | Missense Mutation (SNP) | VAF 125/717 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs1554704033; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 35/227 reads (15%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs766042286, COSV52678471; called by muse, mutect2, varscan2
- PLK1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs751350031, COSV55621304; called by muse, varscan2
- PLXNB2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 85/453 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs766018907, COSV63784396; called by muse, mutect2, varscan2
- POLR3D | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752293727; called by muse, mutect2, varscan2
- POLRMT | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 108/596 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775969994; called by muse, mutect2, varscan2
- POM121C | c.3475G>A p.A1159T (on ENST00000607367; = p.A917T on NM_001099415.3) | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1335997342; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 60/320 reads (19%) | catalogued as rs772047281; called by mutect2, varscan2
- POU5F1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs1207558407; called by muse, mutect2, varscan2
- PPIL2 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs201283292, COSV58604804; called by muse, mutect2, varscan2
- PPM1E | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57578886; called by muse, mutect2, varscan2
- PPP1R32 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs778600925; called by muse, mutect2, varscan2
- PPP1R9A | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748503389, COSV56895023; called by muse, mutect2, varscan2
- PPP2R5D | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 86/462 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747480052, COSV99775928; called by muse, mutect2, varscan2
- PPP3R1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1260240599; called by muse, mutect2, varscan2
- PPRC1 | c.4382dup p.H1462Tfs*10 | Frame Shift Ins (INS) | VAF 71/316 reads (22%) | catalogued as rs772864639; called by mutect2, varscan2
- PRDM13 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760085132, COSV100980585, COSV65030985; called by muse, mutect2, varscan2
- PRDM13 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 84/604 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1316332637; called by muse, mutect2, varscan2
- PRLHR | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 120/545 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750948366, COSV53302690; called by muse, mutect2, varscan2
- PRMT1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV99773700; called by muse, mutect2, varscan2
- PRPF40A | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs760056687; called by muse, varscan2
- PRR19 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 114/641 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.563); catalogued as COSV100003800; called by muse, mutect2, varscan2
- PRUNE2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs745462357, COSV100943317; called by muse, mutect2, varscan2
- PSKH2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 98/687 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs750519355, COSV52609849; called by muse, mutect2, varscan2
- PSMD4 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); catalogued as rs930825880; called by muse, mutect2, varscan2
- PSMG1 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs202176293; called by muse, mutect2, varscan2
- PTK7 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 94/540 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs750381359; called by muse, mutect2, varscan2
- PTMS | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs867073491; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 46/256 reads (18%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPRT | c.904del p.A302Pfs*21 | Frame Shift Del (DEL) | VAF 65/412 reads (16%) | catalogued as COSV62008630; called by mutect2, pindel, varscan2
- PVRIG | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 93/531 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52780877; called by muse, mutect2, varscan2
- PXDN | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53227915; called by muse, varscan2
- PXN | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs201921559, COSV57221596; called by muse, mutect2, varscan2
- QARS1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764216449, COSV60275524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QSOX1 | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 67/408 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.867); catalogued as rs1013295287; called by muse, mutect2, varscan2
- RAD18 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs781347031, COSV53749356; called by muse, mutect2, varscan2
- RANBP2 | c.7265G>A p.R2422H | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51696555; called by muse, mutect2, varscan2
- RAPGEF4 | c.2538del p.K846Nfs*5 | Frame Shift Del (DEL) | VAF 32/219 reads (15%) | catalogued as COSV51380239; called by mutect2, pindel, varscan2
- RAPGEFL1 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.911); catalogued as rs1034804333; called by muse, mutect2, varscan2
- RBM10 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100237976; called by muse, mutect2, varscan2
- RBM12B | c.1706del p.P569Rfs*91 | Frame Shift Del (DEL) | VAF 59/447 reads (13%) | catalogued as COSV101234463; called by mutect2, pindel, varscan2
- RBSN | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773052562, COSV53794840; called by muse, mutect2, varscan2
- REEP3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs747010885, COSV53424789; called by muse, mutect2, varscan2
- RERG | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 88/500 reads (18%) | catalogued as COSV99917223; called by muse, mutect2, varscan2
- REXO4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 66/436 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs782112282; called by muse, mutect2, varscan2
- RGS14 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101281700; called by muse, mutect2, varscan2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 102/350 reads (29%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIN1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 126/547 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs533409856, COSV60925454; called by muse, mutect2, varscan2
- RIPK4 | c.1321C>T p.R441W (on ENST00000352483; = p.R393W on NM_020639.3) | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs141192148; called by muse, mutect2, varscan2
- RMDN2 | c.976del p.M326Wfs*39 (on ENST00000354545 / NM_001322212.2; = p.M504Wfs*39 on NM_144713.5) | Frame Shift Del (DEL) | VAF 33/234 reads (14%) | catalogued as rs770517879; called by mutect2, pindel, varscan2
- RMDN3 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as rs370466451; called by muse, mutect2, varscan2
- ROBO4 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 91/470 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs748266690; called by muse, mutect2, varscan2
- ROCK2 | c.980del p.N327Ifs*7 | Frame Shift Del (DEL) | VAF 21/169 reads (12%) | catalogued as COSV55077330; called by mutect2, pindel, varscan2
- RP1L1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 93/576 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs900593447, COSV66754572; called by muse, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 70/380 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, varscan2
- RPL27A | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 54/377 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs562282613; called by muse, mutect2
- RPL7 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs976896432; called by muse, mutect2, varscan2
- RPRD1A | c.799del p.R267Afs*3 | Frame Shift Del (DEL) | VAF 45/252 reads (18%) | catalogued as COSV100442356; called by mutect2, pindel*, varscan2
- RREB1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1418970900; called by muse, mutect2, varscan2
- RREB1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 105/608 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs754945001, COSV100619301; called by muse, mutect2, varscan2
- RREB1 | c.4678C>T p.R1560W | Missense Mutation (SNP) | VAF 59/471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748378386; called by muse, mutect2, varscan2
- RSRC2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs370217351; called by muse, mutect2, varscan2
- RTCB | c.444del p.F148Lfs*16 | Frame Shift Del (DEL) | VAF 62/380 reads (16%) | catalogued as COSV53279021; called by mutect2, pindel, varscan2
- RUNDC3B | c.23del p.G8Afs*2 | Frame Shift Del (DEL) | VAF 74/436 reads (17%) | catalogued as rs1554445885; called by mutect2, pindel, varscan2
- RYR2 | c.4546G>A p.G1516R | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287904079, COSV63689022; called by muse, mutect2, varscan2
- SAFB2 | c.2194T>C p.Y732H | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1225396177; called by muse, mutect2, varscan2
- SAMD4B | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 98/529 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as rs758480676; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 60/300 reads (20%) | catalogued as COSV59083791; called by mutect2, varscan2
- SARDH | c.568_569del p.L190Vfs*43 | Frame Shift Del (DEL) | VAF 70/417 reads (17%) | catalogued as rs1452007530; called by pindel, varscan2
- SCN5A | c.5756G>A p.R1919H (on ENST00000333535 / NM_198056.3; = p.R1918H on NM_000335.5) | Missense Mutation (SNP) | VAF 103/528 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs141107387; called by muse, mutect2, varscan2
- SCRIB | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 98/596 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs942429013; called by muse, mutect2, varscan2
- SDC3 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 100/520 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs201140173, COSV100232519; called by muse, mutect2, varscan2
- SDR16C5 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 65/383 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1211979027; called by muse, mutect2, varscan2
- SECISBP2L | c.2149C>T p.R717* (on ENST00000559471 / NM_001193489.2; = p.R672* on NM_014701.4) | Nonsense Mutation (SNP) | VAF 40/248 reads (16%) | catalogued as rs1269356789; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 52/293 reads (18%) | catalogued as COSV60921783; called by mutect2, pindel, varscan2
- SEMA3A | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54880077; called by muse, varscan2
- SEMA3G | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs541950335; called by muse, mutect2, varscan2
- SEMA4A | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV61772407; called by muse, mutect2, varscan2
- SEMA4F | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1275571318; called by muse, mutect2, varscan2
- SEMA6A | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 63/404 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.793); catalogued as rs754006049; called by muse, mutect2, varscan2
- SERTAD1 | c.113del p.P38Rfs*34 | Frame Shift Del (DEL) | VAF 52/413 reads (13%) | catalogued as COSV100781697; called by mutect2, pindel, varscan2
- SETD1A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765554192, COSV52679658; called by muse, mutect2, varscan2
- SGIP1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.166); catalogued as rs143844959; called by muse, mutect2, varscan2
- SH3RF1 | c.1904C>A p.P635H | Missense Mutation (SNP) | VAF 85/524 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV52921266; called by muse, mutect2, varscan2
- SH3RF3 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 115/574 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs373580159; called by muse, varscan2
- SHANK1 | c.6272G>A p.G2091D | Missense Mutation (SNP) | VAF 96/537 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99521610; called by muse, mutect2, varscan2
- SHANK1 | c.1266del p.P424Qfs*5 | Frame Shift Del (DEL) | VAF 81/500 reads (16%) | catalogued as rs1568442066; called by mutect2, pindel, varscan2
- SHROOM1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 132/719 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1369747297; called by muse, mutect2, varscan2
- SIPA1L2 | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs760457506; called by muse, mutect2, varscan2
- SIPA1L3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 104/523 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs148442622; called by muse, mutect2, varscan2
- SLC12A9 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760173586; called by muse, mutect2, varscan2
- SLC1A6 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as rs149934975; called by muse, varscan2
- SLC22A13 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751044530, COSV100314450; called by muse, mutect2, varscan2
- SLC2A10 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 88/557 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280877; ClinVar: uncertain significance; called by muse, varscan2
- SLC2A5 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142118350; called by muse, mutect2, varscan2
- SLC40A1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 86/440 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs752593581, COSV53725387; called by muse, mutect2
- SLC46A3 | c.926del p.L309* | Frame Shift Del (DEL) | VAF 50/231 reads (22%) | catalogued as COSV99906530; called by mutect2, pindel, varscan2
- SLC4A10 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as rs1365933953, COSV55783084; called by muse, mutect2, varscan2
- SLC6A12 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 69/415 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs779060532, COSV62885322; called by muse, mutect2, varscan2
- SLC6A15 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 54/313 reads (17%) | catalogued as rs1425540176, COSV99880203; called by muse, mutect2, varscan2
- SLC9B1 | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99599059; called by muse, mutect2
- SLCO1B3 | c.833del p.F278Sfs*22 | Frame Shift Del (DEL) | VAF 27/191 reads (14%) | catalogued as rs751405974; called by mutect2, varscan2
- SMARCC1 | c.783del p.K261Nfs*7 | Frame Shift Del (DEL) | VAF 35/215 reads (16%) | catalogued as COSV99592634; called by mutect2, pindel, varscan2
- SMC6 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 73/388 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1449974269; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 38/194 reads (20%) | catalogued as rs760667210; called by mutect2, varscan2
- SMCHD1 | c.3999del p.F1333Lfs*20 | Frame Shift Del (DEL) | VAF 58/307 reads (19%) | catalogued as rs1172818643; called by mutect2, pindel, varscan2
- SMPD3 | c.1557C>T p.D519= | Splice Region (SNP) | VAF 53/293 reads (18%) | catalogued as rs754364318; called by muse, mutect2, varscan2
- SNRNP48 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs778128352, COSV100672887; called by muse, mutect2, varscan2
- SNX13 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as COSV68066853; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 43/289 reads (15%) | catalogued as rs768873484; called by mutect2, varscan2
- SORCS1 | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.52); catalogued as COSV53913466; called by muse, mutect2, varscan2
- SORL1 | c.2945G>A p.S982N | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV52764773; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 108/801 reads (13%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPATA20 | c.1672G>A p.G558S (on ENST00000356488 / NM_001258372.1; = p.G574S on NM_022827.4) | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1459622290, COSV50065907; called by muse, mutect2, varscan2
- SPHKAP | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780312968, COSV60888486; called by muse, mutect2, varscan2
- SPSB2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1555133744, COSV51289986; called by muse, mutect2, varscan2
- SPTB | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1009915997, COSV67629973; called by muse, mutect2, varscan2
- SPTBN5 | c.6412G>A p.A2138T | Missense Mutation (SNP) | VAF 95/496 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1318265278; called by muse, mutect2, varscan2
- SRRM2 | c.7602_7604del p.S2556del | In Frame Del (DEL) | VAF 96/478 reads (20%) | catalogued as rs746632079; called by pindel, varscan2
- SRRM4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs189389386, COSV99939707; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214dup p.F407Lfs*55 | Frame Shift Ins (INS) | VAF 50/314 reads (16%) | catalogued as rs752994755; called by mutect2, varscan2
- STT3A | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as rs1383636042, COSV101205096, COSV104429732; called by muse, varscan2
- STX8 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs755945693, COSV100111002, COSV60488456; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | catalogued as rs747003550; called by mutect2, varscan2
- SUSD2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 133/654 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs778008563; called by muse, mutect2, varscan2
- SYBU | c.1586T>C p.M529T (on ENST00000276646 / NM_001099754.2; = p.M528T on NM_017786.6) | Missense Mutation (SNP) | VAF 69/495 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1261724854, COSV52621814; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 49/205 reads (24%) | catalogued as rs753462162; called by mutect2, varscan2
- SYNCRIP | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs759373270, COSV62288495; called by muse, varscan2
- SYNE2 | c.3491del p.N1164Mfs*15 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs36002065; called by mutect2, pindel, varscan2
- TAAR1 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1237178598; called by muse, mutect2, varscan2
- TAB2 | c.2027del p.L676* | Frame Shift Del (DEL) | VAF 78/524 reads (15%) | catalogued as rs749262561; called by mutect2, pindel, varscan2
- TAF11L13 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1215418381, COSV72825734; called by muse, mutect2, varscan2
- TARS2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs370560290; called by muse, mutect2, varscan2
- TBXAS1 | c.1571del p.N524Mfs*29 | Frame Shift Del (DEL) | VAF 46/247 reads (19%) | catalogued as rs748691839; called by mutect2, pindel, varscan2
- TBXT | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 263/792 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs764888773, COSV51617655, COSV99752710; called by muse, varscan2
- TCERG1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 91/612 reads (15%) | catalogued as COSV99695402; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 80/348 reads (23%) | catalogued as rs748021112; called by mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 58/357 reads (16%) | catalogued as COSV61906772; called by mutect2, varscan2
- TCHH | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV64275207; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 44/214 reads (21%) | catalogued as rs763438715; called by mutect2, varscan2
- TCN2 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs560678006; called by muse, mutect2, varscan2
- TCTE1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 93/606 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs533816994; called by muse, mutect2, varscan2
- TDRD12 | c.1790del p.N597Ifs*25 | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | catalogued as rs1052864503; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 44/261 reads (17%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 61/327 reads (19%) | catalogued as rs753315680; called by mutect2, pindel, varscan2
- TFDP2 | c.463G>A p.A155T (on ENST00000489671 / NM_001178139.2; = p.A94T on NM_006286.5) | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1251458626; called by muse, mutect2, varscan2
- TGFBR1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66625243, COSV66627439; called by muse, mutect2, varscan2
- THAP7 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs1445240365, COSV53145551; called by muse, mutect2
- THBS2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 79/506 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781465215; called by muse, mutect2, varscan2
- THBS4 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs367686922; called by muse, mutect2, varscan2
- TLN1 | c.4903G>A p.G1635S | Missense Mutation (SNP) | VAF 77/450 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as rs749077133; called by muse, mutect2, varscan2
- TMEM18 | c.421T>C p.*141Rext*42 | Nonstop Mutation (SNP) | VAF 42/244 reads (17%) | catalogued as COSV55243281; called by muse, mutect2, varscan2
- TMEM181 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs372660843; called by muse, mutect2, varscan2
- TMEM198 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); catalogued as rs1473056656; called by muse, mutect2, varscan2
- TMEM63B | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751719789; called by muse, mutect2, varscan2
- TMTC1 | c.1058G>A p.R353Q (on ENST00000539277 / NM_001193451.2; = p.R245Q on NM_175861.3) | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375595309; called by muse, mutect2, varscan2
- TNFRSF9 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs748890197, COSV66349098; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 38/222 reads (17%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNKS1BP1 | c.3656dup p.I1220Nfs*11 | Frame Shift Ins (INS) | VAF 101/539 reads (19%) | catalogued as rs1565040520; called by mutect2, pindel, varscan2
- TNMD | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150078800; called by muse, mutect2, varscan2
- TNPO2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs778630699, COSV63507859; called by muse, varscan2
- TNS1 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 85/463 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs375058582, COSV99410363; called by muse, mutect2, varscan2
- TRAF7 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs766165474; called by muse, mutect2, varscan2
- TRAJ30 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 62/288 reads (22%) | catalogued as rs866941373; called by muse, varscan2
- TRAPPC9 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 89/539 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs769691517, COSV66907020; called by muse, mutect2, varscan2
- TRIM45 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs533016681, COSV56712893; called by muse, varscan2
- TRIM72 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 134/657 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.568); catalogued as COSV59067363; called by muse, mutect2, varscan2
- TRIR | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1486166952; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPC1 | c.1506del p.F502Lfs*7 (on ENST00000476941 / NM_001251845.2; = p.F468Lfs*7 on NM_003304.4) | Frame Shift Del (DEL) | VAF 55/366 reads (15%) | catalogued as COSV56422836; called by mutect2, pindel, varscan2
- TSC1 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1060503200, COSV53768377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC22D4 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 135/666 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.976); catalogued as rs374915525; called by muse, mutect2, varscan2
- TSHZ1 | c.688C>T p.R230C (on ENST00000580243 / NM_001308210.2; = p.R185C on NM_005786.6) | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201310318; called by muse, varscan2
- TSPYL2 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs374502411; called by muse, mutect2, varscan2
- TTC3 | c.1769del p.N590Tfs*4 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs752525442; called by mutect2, varscan2
- TTC33 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61802319, COSV61802560; called by muse, mutect2, varscan2
- TTC34 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 101/547 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257455325; called by muse, mutect2, varscan2
- TTF1 | c.668del p.K223Rfs*45 | Frame Shift Del (DEL) | VAF 65/321 reads (20%) | catalogued as rs765042099; called by mutect2, varscan2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | catalogued as rs751135082; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL10 | c.361C>T p.R121W (on ENST00000379289 / NM_001130045.2; = p.R48W on NM_153254.3) | Missense Mutation (SNP) | VAF 124/608 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV101016876; called by muse, varscan2
- TTLL13P | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs371974190; called by muse, mutect2, varscan2
- TUBA3E | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs751114501; called by muse, mutect2, varscan2
- TUT4 | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 52/266 reads (20%) | catalogued as COSV57115535; called by muse, mutect2, varscan2
- UAP1 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1458938846; called by muse, mutect2, varscan2
- UBR3 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs748028932, COSV55847157; called by muse, mutect2, varscan2
- UBR4 | c.13142C>T p.P4381L | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144615268; called by muse, mutect2, varscan2
- UBXN6 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs563472721, COSV56673428; called by muse, mutect2, varscan2
- USP13 | c.1854del p.L619Yfs*15 | Frame Shift Del (DEL) | VAF 53/281 reads (19%) | catalogued as rs1333558391; called by mutect2, pindel, varscan2
- USP19 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752502439, COSV60045903; called by muse, mutect2, varscan2
- VASN | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 122/619 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs750677669; called by muse, mutect2, varscan2
- VCL | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs534101808, COSV53014542; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 40/208 reads (19%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13B | c.2879T>C p.L960S | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs775378782; called by muse, mutect2, varscan2
- VPS13D | c.12743C>T p.A4248V | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779850187, COSV50621319; called by muse, mutect2, varscan2
- VPS35L | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770474820, COSV99221116; called by muse, mutect2, varscan2
- VSNL1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1260171799, COSV54597194; called by muse, mutect2, varscan2
- VWA1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1463298717; called by muse, mutect2, varscan2
- VWA5B2 | c.731dup p.H245Sfs*19 | Frame Shift Ins (INS) | VAF 50/350 reads (14%) | catalogued as rs770124856; called by mutect2, varscan2
- WDR27 | c.1849dup p.A617Gfs*14 | Frame Shift Ins (INS) | VAF 42/380 reads (11%) | catalogued as rs768578801; called by mutect2, pindel, varscan2
- WDR33 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs552443294; called by muse, mutect2, varscan2
- WDR59 | c.2688C>T p.I896= | Splice Region (SNP) | VAF 54/250 reads (22%) | catalogued as rs147964482; called by muse, mutect2, varscan2
- WDR81 | c.4094T>C p.L1365P (on ENST00000409644 / NM_001163809.2; = p.L314P on NM_152348.4) | Missense Mutation (SNP) | VAF 130/680 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156288032; called by muse, mutect2, varscan2
- WDR87 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 84/420 reads (20%) | catalogued as rs868393245; called by muse, mutect2, varscan2
- WDR97 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 111/721 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs1361915531; called by muse, mutect2, varscan2
- WNK2 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419006172; called by muse, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 134/500 reads (27%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WTIP | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 74/452 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs928404384; called by muse, varscan2
- YIF1B | c.869G>A p.R290H (on ENST00000339413 / NM_001039673.3; = p.R275H on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/530 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747437505; called by muse, varscan2
- ZBP1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs376946202; called by muse, varscan2
- ZBP1 | c.946G>T p.G316W | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748788161; called by muse, varscan2
- ZBTB18 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 72/441 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62397154; called by muse, mutect2, varscan2
- ZBTB7A | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100475865; called by muse, mutect2, varscan2
- ZC3H12C | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99585058; called by muse, mutect2, varscan2
- ZC3H12D | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 96/620 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs1202727394; called by muse, mutect2, varscan2
- ZC3H13 | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV99667716; called by muse, varscan2
- ZC3H14 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs746385996, COSV99193003; called by muse, mutect2, varscan2
- ZCCHC7 | c.1192del p.I398* | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | catalogued as rs1564275792; called by mutect2, pindel, varscan2
- ZFHX3 | c.10294T>C p.S3432P | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51723082; called by muse, varscan2
- ZFP41 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 86/583 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.933); catalogued as rs775559357, COSV58088425; called by muse, mutect2, varscan2
- ZFPM2 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs778808844; called by muse, mutect2, varscan2
- ZHX1 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 80/566 reads (14%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.859); catalogued as rs770197354; called by muse, mutect2, varscan2
- ZNF10 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776969365, COSV50213909; called by muse, varscan2
- ZNF157 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV65659788; called by muse, mutect2, varscan2
- ZNF181 | c.1044_1045del p.Y349* | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | catalogued as rs753886206; called by pindel, varscan2
- ZNF202 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 81/453 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs756925638, COSV60247219; called by muse, mutect2, varscan2
- ZNF318 | c.2633T>C p.I878T | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58934053; called by muse, mutect2, varscan2
- ZNF329 | c.1517G>A p.S506N | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1422045850, COSV100798799; called by muse, mutect2, varscan2
- ZNF341 | c.125del p.P42Lfs*28 | Frame Shift Del (DEL) | VAF 80/418 reads (19%) | catalogued as rs1427517039; called by mutect2, pindel, varscan2
- ZNF469 | c.36del p.T13Pfs*2 | Frame Shift Del (DEL) | VAF 56/395 reads (14%) | catalogued as rs1350473091; called by pindel, varscan2
- ZNF469 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 90/531 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs865907429; called by muse, mutect2, varscan2
- ZNF521 | c.3316G>A p.G1106S | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100832175, COSV64122274; called by muse, mutect2, varscan2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 47/277 reads (17%) | catalogued as COSV100329754, COSV57108094; called by mutect2, pindel, varscan2
- ZNF575 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 144/689 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs754887004; called by muse, mutect2, varscan2
- ZNF608 | c.1639T>G p.C547G | Missense Mutation (SNP) | VAF 86/544 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60439585; called by muse, mutect2, varscan2
- ZNF626 | c.933A>C p.K311N | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs782584486; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 27/208 reads (13%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF70 | c.242dup p.G82Rfs*7 | Frame Shift Ins (INS) | VAF 62/397 reads (16%) | catalogued as rs775749922; called by mutect2, pindel, varscan2
- ZNF701 | c.1207C>T p.R403C (on ENST00000301093; = p.R337C on NM_018260.3) | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs150530453; called by muse, mutect2, varscan2
- ZNF735 | c.381del p.K127Nfs*6 | Frame Shift Del (DEL) | VAF 32/203 reads (16%) | catalogued as rs781384768, COSV70035178; called by pindel, varscan2
1,308 further variants in this file (766 protein-altering or splice-affecting, 460 silent, 82 other) are not listed here.
